Gene-level copy-number profile of tumor specimen 2f2e5477-42a4-4906-a943-bf7f80 from CPTAC case 11LU035, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: GX; Age at diagnosis: 59.3 years (21,677 days).
Specimen 2f2e5477-42a4-4906-a943-bf7f80: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 54fbce4f-2cfb-4c6a-b4bf-278d1314ff39.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 6b328a7b-2d97-4a02-8a6c-89f96a (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,728 have no estimate.
https://portal.gdc.cancer.gov/files/64f53122-47fc-4471-b62d-63389c217b6a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 545; copy number 1: 10,667; copy number 2: 38,267; copy number 3: 5,803; copy number 4: 2,505; copy number 5: 844; copy number 6: 257; copy number 7: 7.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:39,355,669–39,655,531, 10 genes: SPATA31A1, BX005214.3, FAM74A1, BX005214.1, BX005214.2, ZNF658B, SKP1P3, FKBP4P2, SDR42E1P1, ATP5F1AP8.
- chr9:40,105,822–40,806,344, 12 genes: AL773545.3, CDRT15P14, AL773545.1, AL773545.2, ANKRD20A2P, RNU6-1269P, CNN2P2, GXYLT1P3, AL591471.1, AL353626.3, RNU6-156P, AL353626.1.
- chr16:32,116,700–32,132,724, 2 genes (within-gene range 0–2): AC142381.2, AC133485.7.
- chr19:20,416,514–20,417,069, 1 gene (within-gene range 0–1): BNIP3P22.
- chr19:20,443,215–20,443,725, 1 gene (within-gene range 0–1): BNIP3P23.
- chr21:46,690,764–46,691,226, 1 gene: RPL23AP4.
- chr22:35,703,803–35,704,176, 1 gene: MRPS16P3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,108 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–29,217,115, 420 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr5:29,001,760–45,895,970, 256 genes, copy number 6 (broad region; genes not listed).
- chr7:62,275,361–63,154,934, 7 genes, copy number 7: AC128676.1, RNU6-417P, AC069285.2, AC069285.3, ZNF90P3, SAPCD2P4, SEPTIN14P1.
- chr7:98,106,862–119,907,397, 420 genes, copy number 5 (broad region; genes not listed).
- chr9:39,734,670–39,741,193, 2 genes, copy number 5: RAB28P1, RBPJP5.
- chr9:39,886,861–39,892,895, 3 genes, copy number 5: RN7SL763P, SNORA70, CR769767.1.

Autosomal genes at a single copy (total copy number 1): 8,354. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
